CCDI case PBBYJY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/83b57595-aa93-4fe6-9e5b-1625fe3803d6

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Large cell medulloblastoma: ICD-O-3 morphology code: 9474/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.8 years (3,928 days).

Biospecimens (3 samples)
- Sample 0DKIHW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKII8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKIII: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
